TCGA case TCGA-28-5214 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Cedars Sinai. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/cb4f4617-8260-475d-a650-2f049474b001

Demographics
Sex at birth: male; Race: white; Age at index: 53 years; Vital status: Dead; Days to death: 713 days (2.0 years).

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 53.4 years (19,520 days); Year of diagnosis: 2010; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 20 days; Days to treatment end: 67 days; Treatment dose: 6,000 cGy; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 20 days; Treatment outcome: Treatment Ongoing; Course number: 1; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 20 days; Treatment outcome: Treatment Ongoing; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Days to treatment start: 20 days; Days to treatment end: 62 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 20 days; Number of cycles: 2; Treatment outcome: Treatment Ongoing; Prescribed dose: 1750; Prescribed dose units: mg/m2/day; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bevacizumab + Irinotecan Hydrochloride; Initial disease status: Recurrent Disease; Days to treatment start: 262 days; Treatment outcome: Treatment Ongoing; Prescribed dose: 10; Prescribed dose units: mg/kg; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 324 days; Days to treatment end: 324 days; Treatment dose: 1,600 cGy; Number of fractions: 1; Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Radiation, Stereotactic/Gamma Knife/SRS; Initial disease status: Recurrent Disease; Days to treatment start: 324 days; Days to treatment end: 324 days; Treatment dose: 1,600 cGy; Course number: 2; Number of fractions: 1; Treatment anatomic sites: Locoregional Site.
2. Progression of diagnosis 1 (Glioblastoma). Age at diagnosis: 54.1 years (19,767 days); Days to diagnosis: 247 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 324 days.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS.

Follow-up (5 entries)
- Day 247 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to progression: 247 days.
- Days to follow up: 432 days (1.2 years); Disease response: With Tumor.
- Karnofsky performance status: 70; Timepoint: Prior to Adjuvant Therapy.
- Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Timepoint: Post Initial Treatment.
- Follow-up contact recording only the day: day 713.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-28-5214-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 0.8; Intermediate dimension: 0.6; Shortest dimension: 0.2.
  Slide TCGA-28-5214-01A-01-BS1: Section location: Bottom; Percent tumor cells: 100; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
  Slide TCGA-28-5214-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
- Sample TCGA-28-5214-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Performance status timing: Pre-Adjuvant Therapy.
- Drug treatment 1: Regimen number: 01; Pharmaceutical therapy drug name: Temodar.
- Drug treatment 1, Route of administrations: Route of administration: PO.
- Drug treatment 3: Regimen number: 02; Pharmaceutical therapy drug name: CPT 11; Therapy regimen: Recurrence.
- Drug treatment 3, Route of administrations: Route of administration: IV.
- Drug treatment 4: Regimen number: 02; Pharmaceutical therapy drug name: Avastin; Therapy regimen: Recurrence.
- Radiation treatment 3: Radiation type other: Gamma Knife; Therapy regimen: Recurrence.
- Follow-up form 3: Lost to follow-up: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 713 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 713 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 247 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-28-5214-01A-01D-1479-01): tumor purity 0.76, ploidy 2.04, whole-genome doublings 0.
